Somatic mutation profile of tumor specimen MP2PRT-PAPLPE-TMP1-A (aliquot MP2PRT-PAPLPE-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPLPE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,667 days).
Specimen MP2PRT-PAPLPE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f844ece-d882-4c25-86b7-ac40cdfa2eb8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPLPE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPLPE-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27aebb98-f052-4472-8f98-9c94b5679a3f

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACHE | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 46/662 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs781114815; called by muse, mutect2
- ESPL1 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 168/425 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1461716647; called by muse, varscan2
- KIF4B | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 149/540 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753391654, COSV70529106; called by muse, mutect2, varscan2
- OR8A1 | c.488T>A p.M163K | Missense Mutation (SNP) | VAF 20/388 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.756); catalogued as rs747691731; called by muse, mutect2
- PACS1 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 17/440 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.15); catalogued as rs1224491985; called by muse, mutect2
- ALDH1A1 | c.889T>C p.Y297H | Missense Mutation (SNP) | VAF 84/285 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- BEX5 | c.225G>A p.M75I | Missense Mutation (SNP) | VAF 156/248 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- EML5 | c.4408A>C p.K1470Q (on ENST00000380664; = p.K1478Q on NM_183387.3) | Missense Mutation (SNP) | VAF 104/360 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- HNRNPU | c.1558C>G p.R520G (on ENST00000283179; = p.R582G on NM_004501.3) | Missense Mutation (SNP) | VAF 104/383 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 107/420 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- PIGW | c.846G>C p.K282N | Missense Mutation (SNP) | VAF 24/500 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2
- PRDX4 | c.370T>C p.C124R | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRK | c.996G>A p.M332I | Missense Mutation (SNP) | VAF 40/648 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.041); called by muse, mutect2
- GCC2 | c.3906A>G p.L1302= | Silent (SNP) | VAF 116/353 reads (33%) | called by muse, mutect2, varscan2
- IGLV4-69 | c.359dup | Silent (INS) | VAF 72/129 reads (56%) | called by mutect2, pindel, varscan2
- PLEKHH1 | c.3651C>T p.T1217= | Silent (SNP) | VAF 112/338 reads (33%) | catalogued as rs749453340; called by muse, mutect2, varscan2
